CCDI case PBBXKW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/5808603e-205e-4cb4-95ec-2f3708206310

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 8.8 years (3,207 days).

Biospecimens (3 samples)
- Sample 0DJVP3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJVPE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJVPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
